TCGA case TCGA-BF-AAOU — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dfe9d2bd-2317-4103-b493-41c5469e08a0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 73 years; Vital status: Alive.

Diagnoses (2)
1. Amelanotic melanoma (the primary disease): ICD-O-3 morphology code: 8730/3; ICD-10 code: C44.5; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,750 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 476 days (1.3 years); Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 13 days; Disease response: Tumor Free.
- Days to follow up: 476 days (1.3 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 50 kg; Height: 160 cm; BMI: 19.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BF-AAOU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-BF-AAOU-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BF-AAOU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BF-AAOU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 12; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 476 days; disease-specific survival: no event (censored), 476 days; progression-free interval: no event (censored), 476 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BF-AAOU-01A-12D-A396-01): tumor purity 0.59, ploidy 1.89, whole-genome doublings 0.
